MMRF case MMRF_1327 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7873c1f5-3175-4b68-b8e0-00c1d2b36801

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.5 years (26,113 days); ISS stage: III; Days to last known disease status: 1 day; Days to last follow up: 1 day.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (2 entries)
- Days to follow up: -4 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.45 mmol/L.
- Absolute Neutrophil 4 ×10⁹/L.
- M Protein 4.46 g/dL.
- Albumin 31 g/L.
- C-Reactive Protein 0.307 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL.
- Leukocytes 5.7 ×10⁹/L.
- Platelets 263 ×10⁹/L.
- Glucose 4.24 mmol/L.
- Beta 2 Microglobulin 7.04 µg/mL.
- Immunoglobulin M 0.1 g/L.
- Hemoglobin 6.88 mmol/L.
- Creatinine 106 µmol/L.
- Blood Urea Nitrogen 8.21 mmol/L.
- Immunoglobulin G 57.4 g/L.
- Total Protein 10.7 g/dL.
- Immunoglobulin A 0.08 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 77.6 mg/dL.
- Lactate Dehydrogenase 4.65 µkat/L.

Other clinical attributes
- Day -4: Weight: 68 kg; Height: 163 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1327_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1327_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
